CCDI case PBBVFM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/096ec85b-c529-45e0-bbc1-98a23cace0c5

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.5 years (2,724 days).

Biospecimens (3 samples)
- Sample 0DI3IZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI3JG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI3M0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
